Somatic mutation profile of tumor specimen ALCH-B2QK-TTP1-A (aliquot ALCH-B2QK-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2QK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mixed invasive mucinous and non-mucinous adenocarcinoma; Age at diagnosis: 66.5 years (24,287 days).
Specimen ALCH-B2QK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68f7a7dc-fdf3-46af-b143-13b7a7811640.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QK-NB1-A (Blood Derived Normal), aliquot ALCH-B2QK-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a4f3ff7-a4a7-407c-be39-15e8215ad4fd

The open-access MAF lists 143 somatic variants for this specimen: 102 protein-altering or splice-affecting, 21 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 21, Intron 14, Splice Site 5, Nonsense Mutation 3, 5'Flank 2, 5'UTR 2, Splice Region 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/789 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AGA | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 48/1062 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs371221470; called by muse, mutect2
- AP002512.3 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 30/606 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs1050088418, COSV54408074, COSV99687833; called by muse, mutect2
- C4orf54 | c.1721C>A p.A574E | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV101552165; called by muse, mutect2
- CACNA1C | c.2525C>A p.T842N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59774020; called by muse, mutect2
- CEP170 | c.2726G>T p.R909L | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV100318223; called by muse, mutect2, varscan2
- CHD9 | c.4460C>T p.S1487F | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs1295169165; called by muse, mutect2
- COL1A2 | c.1036-1G>T p.X346_splice | Splice Site (SNP) | VAF 76/1506 reads (5%) | catalogued as CS941453; called by muse, mutect2
- COL6A5 | c.2650C>G p.R884G | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.43); catalogued as COSV55209422; called by muse, mutect2
- DDX39A | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs749323166; called by muse, mutect2, varscan2
- DEAF1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1219925185; called by muse, varscan2
- DHFR2 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58936660; called by muse, mutect2
- DOLK | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245377789; called by muse, mutect2
- EDF1 | c.291G>A p.T97= | Splice Region (SNP) | VAF 6/78 reads (8%) | catalogued as rs1392367972, COSV56375510; called by muse, mutect2
- FBN2 | c.3976G>A p.V1326I | Missense Mutation (SNP) | VAF 42/570 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs763789417; ClinVar: uncertain significance; called by muse, mutect2
- FSTL5 | c.2445G>T p.K815N | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.199); catalogued as COSV60209987; called by muse, mutect2
- GBA3 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746250725; called by muse, mutect2
- HMCN1 | c.7807C>A p.P2603T | Missense Mutation (SNP) | VAF 24/898 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99630449; called by muse, mutect2
- KCTD8 | c.1268C>A p.T423K | Missense Mutation (SNP) | VAF 54/832 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.079); catalogued as COSV63592402; called by muse, mutect2
- KIF16B | c.3096G>T p.Q1032H | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV61702467; called by muse, mutect2
- MAGEE2 | c.774C>A p.H258Q | Missense Mutation (SNP) | VAF 36/664 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV64897259; called by muse, mutect2
- MUC16 | c.34939C>A p.P11647T | Missense Mutation (SNP) | VAF 44/658 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as rs370736620, COSV67495404; called by muse, mutect2
- MUC4 | c.5231C>T p.P1744L | Missense Mutation (SNP) | VAF 42/1528 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1200261699; called by muse, mutect2
- NLRP12 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs752020239; called by muse, mutect2
- OR2T2 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 183/2492 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61618580; called by muse, mutect2
- OR2Z1 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.973); catalogued as COSV60692534; called by muse, mutect2
- OR8H2 | c.584C>A p.T195N | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV57944670; called by muse, mutect2
- PCDH10 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52089876; called by muse, mutect2
- PHLDB2 | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV67316433; called by muse, mutect2
- PRKD2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 29/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99354327; called by muse, mutect2
- SNTG2 | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100421088; called by muse, mutect2
- TIGD6 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57061323, COSV99697750; called by muse, mutect2
- TRIM58 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 21/694 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100825283; called by muse, mutect2
- TUSC1 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 46/442 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs1166035541; called by muse, mutect2
- VAV1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs776710563; called by mutect2, varscan2
- ZNF222 | c.692G>T p.C231F | Missense Mutation (SNP) | VAF 59/725 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51827796; called by muse, mutect2
- AGAP1 | c.673+1G>T p.X225_splice | Splice Site (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- AOX1 | c.3604G>A p.G1202S | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AR | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ATRX | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- BPGM | c.640A>T p.T214S | Missense Mutation (SNP) | VAF 32/727 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- C8B | c.1469A>C p.K490T | Missense Mutation (SNP) | VAF 40/1088 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CLRN3 | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 60/932 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- COL5A2 | c.3509G>T p.G1170V | Missense Mutation (SNP) | VAF 60/1136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP8B1 | c.1298G>T p.W433L | Missense Mutation (SNP) | VAF 42/539 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMKN | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNTT | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- DPP10 | c.28C>G p.H10D | Missense Mutation (SNP) | VAF 38/690 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- DSC3 | c.2640T>A p.N880K | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ECE2 | c.1512+1G>T p.X504_splice (on ENST00000357474 / NM_001100120.2; = p.X429_splice on NM_001037324.3) | Splice Site (SNP) | VAF 30/380 reads (8%) | called by muse, mutect2
- EIF3H | c.413T>C p.F138S | Missense Mutation (SNP) | VAF 64/724 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- FSTL5 | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- HDAC9 | c.1317A>C p.K439N | Missense Mutation (SNP) | VAF 54/1248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- HELZ | c.2866T>G p.Y956D | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- HLCS | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- IMPG2 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2
- IQCD | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ITGA4 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- KIN | c.980T>A p.L327H | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KNL1 | c.6679G>C p.E2227Q (on ENST00000346991 / NM_170589.5; = p.E2201Q on NM_144508.5) | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KRTAP23-1 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 40/738 reads (5%) | PolyPhen possibly damaging (0.871); called by muse, mutect2
- LRRN3 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 21/375 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- MAGEE2 | c.775A>T p.R259W | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2
- MTMR9 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MXRA5 | c.6639C>A p.D2213E | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.309); called by muse, mutect2
- MYH13 | c.2795A>C p.E932A | Missense Mutation (SNP) | VAF 60/858 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2
- MYH14 | c.5980C>A p.P1994T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.5768A>T p.K1923M | Missense Mutation (SNP) | VAF 47/562 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- NEDD1 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- NELL1 | c.604-1G>C p.X202_splice | Splice Site (SNP) | VAF 14/335 reads (4%) | called by muse, mutect2
- NFKB1 | c.1328C>G p.P443R (on ENST00000394820 / NM_001382627.1; = p.P444R on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- NLRP11 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- OR2G6 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2T35 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 38/561 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, varscan2
- P2RY8 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB11 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 30/536 reads (6%) | called by muse, mutect2
- PDZD7 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 38/686 reads (6%) | called by muse, mutect2
- PFKP | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKHD1L1 | c.6146C>T p.T2049I | Missense Mutation (SNP) | VAF 35/422 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- PLCZ1 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); called by muse, mutect2
- POU1F1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 74/1074 reads (7%) | called by muse, mutect2
- PRKAR1B | c.440+1G>T p.X147_splice | Splice Site (SNP) | VAF 26/303 reads (9%) | called by muse, mutect2
- PRKCG | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 62/694 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB11FIP5 | c.536A>T p.D179V | Missense Mutation (SNP) | VAF 60/736 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RELN | c.2698C>A p.L900I | Missense Mutation (SNP) | VAF 50/786 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); called by muse, mutect2
- RSAD2 | c.848A>T p.H283L | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.7082G>C p.G2361A | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.288); called by muse, varscan2
- S100A7A | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- SHROOM2 | c.4708G>C p.E1570Q | Missense Mutation (SNP) | VAF 20/702 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- SI | c.4217C>A p.T1406N | Missense Mutation (SNP) | VAF 25/408 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- SLC7A11 | c.166A>C p.T56P | Missense Mutation (SNP) | VAF 64/1080 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SNX9 | c.586G>C p.A196P | Missense Mutation (SNP) | VAF 46/565 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SRSF4 | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2
- STK11 | c.482T>G p.I161S | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TLE1 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- TMEM164 | c.687G>T p.L229= (on ENST00000372068 / NM_032227.4; = p.L80= on NM_017698.2) | Splice Region (SNP) | VAF 26/787 reads (3%) | called by muse, mutect2
- TNS1 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- TSHZ3 | c.245G>C p.S82T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2
- UNC80 | c.4751C>G p.T1584R | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- UQCRHL | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 52/737 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- WRN | c.3387C>G p.I1129M | Missense Mutation (SNP) | VAF 42/650 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.264); called by muse, mutect2
- XIRP2 | c.9838C>A p.P3280T (on ENST00000628543; = p.P3455T on NM_152381.6) | Missense Mutation (SNP) | VAF 22/679 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCY3 | c.2475T>A p.P825= | Silent (SNP) | VAF 25/448 reads (6%) | called by muse, mutect2
- ADGRG2 | c.2205C>T p.I735= (on ENST00000379869 / NM_001079858.3; = p.I732= on NM_005756.4) | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- ANKRD13C | c.1476A>C p.P492= | Silent (SNP) | VAF 36/542 reads (7%) | called by muse, mutect2
- ANKRD33B | c.780G>A p.R260= | Silent (SNP) | VAF 25/468 reads (5%) | catalogued as rs1266898753; called by muse, mutect2
- ARHGAP23 | c.3168G>T p.L1056= | Silent (SNP) | VAF 18/287 reads (6%) | called by muse, mutect2
- ARHGAP5 | c.3027A>G p.R1009= | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as rs746950064; called by muse, mutect2
- BOD1L1 | c.7809G>A p.L2603= | Silent (SNP) | VAF 17/458 reads (4%) | called by muse, mutect2
- CAMTA2 | c.2721C>G p.L907= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- COL6A6 | c.5539C>A p.R1847= | Silent (SNP) | VAF 35/655 reads (5%) | called by muse, mutect2
- HUWE1 | c.7362A>T p.G2454= | Silent (SNP) | VAF 20/632 reads (3%) | called by muse, mutect2
- IFT140 | c.2727G>C p.G909= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as rs1240729026; called by muse, mutect2
- MINDY3 | c.1281C>T p.T427= | Silent (SNP) | VAF 31/595 reads (5%) | catalogued as rs1458498227; called by muse, mutect2
- NAT2 | c.405A>G p.L135= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV99674278; called by muse, mutect2
- NDST4 | c.543G>T p.P181= | Silent (SNP) | VAF 31/489 reads (6%) | catalogued as COSV52138200; called by muse, mutect2
- OR51B6 | c.938G>A p.*313= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV66512733; called by mutect2, varscan2
- OR8H2 | c.585C>A p.T195= | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- PDE3B | c.1362A>T p.S454= | Silent (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- SESN2 | c.1014G>T p.R338= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- SVBP | c.18T>A p.R6= | Silent (SNP) | VAF 41/440 reads (9%) | called by muse, mutect2
- TMEM131L | c.843A>G p.L281= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- ZNF213 | c.1167C>T p.A389= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- CAMTA2 | c.-64-643del | Intron (DEL) | VAF 15/160 reads (9%) | called by mutect2, pindel
- CEP41 | c.97+1285T>A | Intron (SNP) | VAF 26/718 reads (4%) | called by muse, mutect2
- FAM177B | c.242-483T>A | Intron (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- GOLGA6L17P | n.589C>A | RNA (SNP) | VAF 79/1539 reads (5%) | called by muse, mutect2
- HADH | c.710-863A>T | Intron (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- IRAG1 | c.2067+16G>T | Intron (SNP) | VAF 12/208 reads (6%) | catalogued as COSV70211346; called by muse, mutect2
- KIF5A | c.3020+25G>A | Intron (SNP) | VAF 28/568 reads (5%) | called by muse, mutect2
- LGALS9B | c.577-25G>T | Intron (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- MC2R | c.-24C>A | 5'UTR (SNP) | VAF 17/361 reads (5%) | catalogued as rs1311405431; called by muse, mutect2
- MEIS1 | c.*77G>T | 3'UTR (SNP) | VAF 26/580 reads (4%) | called by muse, mutect2
- MFAP4 | c.6+20G>C | Intron (SNP) | VAF 35/363 reads (10%) | catalogued as COSV100218841; called by muse, mutect2
- OLFML2A | c.670-430G>T | Intron (SNP) | VAF 32/593 reads (5%) | called by muse, mutect2
- PDCD6 | c.163+3262A>T | Intron (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- SENP2 | chr3:185582575 C>A | 5'Flank (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- SREK1 | c.-279G>A | 5'UTR (SNP) | VAF 64/515 reads (12%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185951 C>T | 5'Flank (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
- TBXAS1 | c.236+17A>T | Intron (SNP) | VAF 38/782 reads (5%) | called by muse, mutect2
- TRIML2 | c.621+775G>T | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- USH1C | c.1285-3891C>A | Intron (SNP) | VAF 33/704 reads (5%) | called by muse, mutect2
- ZEB1 | c.58+44155C>G | Intron (SNP) | VAF 36/596 reads (6%) | called by muse, mutect2
